CCDI case PBCJNH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4ded881e-476f-41ad-8d1e-624cda59baf9

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Malignant tumor, spindle cell type: ICD-O-3 morphology code: 8004/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.6 years (6,423 days).

Biospecimens (3 samples)
- Sample 0DTB8C: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTB8P: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTB8Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
